Somatic mutation profile of tumor specimen TCGA-RY-A847-01A (aliquot TCGA-RY-A847-01A-11D-A36O-08) from TCGA case TCGA-RY-A847, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 45.8 years (16,732 days).
Specimen TCGA-RY-A847-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5b5c389-b26b-4f7f-8d5f-e2cba9586d37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RY-A847-10A (Blood Derived Normal), aliquot TCGA-RY-A847-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b236c22b-f07d-4173-88fb-23bb9f13b168

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 40/98 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BRS3 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV101036519; called by muse, mutect2, varscan2
- FUT5 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs745747279, COSV53138351; called by muse, mutect2, varscan2
- GPAT2 | c.1508G>A p.S503N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.054); catalogued as rs1171449029, COSV64003296; called by muse, mutect2, varscan2
- MUC16 | c.34604C>T p.T11535M | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.818); catalogued as rs111231164, COSV67472305; called by muse, mutect2, varscan2
- OR2T12 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58777085; called by muse, mutect2, varscan2
- PTPRN | c.293A>G p.H98R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV99833862; called by muse, mutect2
- RASGRF1 | c.1595C>T p.T532M | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs1226471162, COSV69182369, COSV69182439; called by muse, mutect2, varscan2
- RELN | c.5321G>A p.G1774E | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773341210, COSV100633167; called by mutect2, varscan2
- TGIF2LY | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV100339651; called by muse, mutect2, varscan2
- ZBTB20 | c.1907G>A p.C636Y (on ENST00000474710 / NM_001164342.2; = p.C563Y on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100613358; called by muse, mutect2
- ZNF148 | c.1531del p.E511Kfs*8 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, varscan2
- FKBPL | c.441C>T p.G147= | Silent (SNP) | VAF 121/285 reads (42%) | catalogued as COSV64322384; called by muse, mutect2, varscan2
- OR4A47 | c.108C>A p.T36= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV101487060; called by muse, mutect2, varscan2
